Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4827, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4827-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: SPLEEN, (126 GRAMS), SPLENECTOMY --

- A. RECENT SUBCAPSULAR/CAPSULAR HEMORRHAGE WITH GELFOAM MATERIAL FOCALLY PRESENT ON SPLENIC SURFACE, AND FOCAL ORGANIZED SUBCAPSULAR HEMORRHAGE AND FIBROSIS.
- B. PROMINENT WHITE PULP WITH RELATIVE LYMPHOID HYPERPLASIA.
- C. NO EVIDENCE OF MALIGNANCY.

PART 2: KIDNEY AND ADRENAL GLAND, LEFT, RADICAL NEPHRECTOMY --

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR AND GRANULAR CELL) TYPE, PRESENT IN THE UPPER AND MID PORTIONS OF THE KIDNEY, EXTENDING FROM SUPERFICIAL CORTEX THROUGH DEEP MEDULLA.
- B. FUHRMAN'S NUCLEAR GRADE VARIES FROM GRADE II TO GRADE IV, WITH FOCAL NECROSIS AND CALCIFICATION.
- C. MAXIMUM DIAMETER OF THE NEOPLASM IS 11 CM.
- D. CARCINOMA EXTENDS THROUGH THE RENAL CAPSULE INTO PERIRENAL ADIPOSE TISSUE PERIPHERALLY, AND INTO RENAL SINUS ADIPOSE TISSUE MORE CENTRALLY, BUT DOES NOT INVOLVE GEROTA'S FASCIA.
- E. LARGE OCCLUSIVE CARCINOMATOUS THROMBUS IS PRESENT IN THE MAIN RENAL VEIN WITH THROMBUS EXTENDING TO THE RENAL VEIN MARGIN.
- F. REMAINING SURGICAL MARGINS OF RESECTION (RENAL ARTERY, URETER, AND GEROTA'S FASCIA) ARE FREE OF CARCINOMA.
- G. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- H. BENIGN ADRENAL GLAND WITH NO SIGNIFICANT PATHOLOGY.
- I. TNM STAGE: pT3b NX MX.
- J. TNM MAXIMUM HISTOLOGIC GRADE = G4.

SYNOPTIC - PRIMARY KIDNEY/RENAL PELVIS/URETER TUMORS

- A. Side: 2 1. Right 2. Left
- B. Location: 1
- 1. Kidney (parenchyma - cortex/medulla)
- 2. Kidney (pelvis)
- 3. Ureter
- 4. Kidney and ureter
- C. Procedure: 3
- 1. Partial nephrectomy
- 2. Simple nephrectomy
- 3. Radical nephrectomy
- 4. Ureterectomy
- 5. Other
- D. Size of neoplasm (maximum dimension; if multicentric, size of largest mass): 11.0 cm
- E. Type of malignant neoplasm: 1
- 1. Renal cell carcinoma, clear cell type (includes non-papillary granular cell RCC)
- 2. Renal cell carcinoma, chromophil cell type (papillary RCC, no clear cell component)
- 3. Renal cell carcinoma, chromophobe cell type
- 4. Renal cell carcinoma, oncocytic
- 5. Renal cell carcinoma, sarcomatoid
- 6. Collecting duct carcinoma
- 7. Urothelial carcinoma, TCCa (non-invasive)
- 8. Urothelial carcinoma, TCCa (invasive ± in-situ)
- 9. Urothelial carcinoma, squamous carcinoma
- 10. Urothelial carcinoma, adenocarcinoma
- 11. Urothelial carcinoma, small cell/neuroendocrine carcinoma
- 12. Urothelial carcinoma, mixed
- 13. Juxtaglomerular cell tumor
- 14. Wilms' tumor
- 15. Rhabdoid tumor
- 16. Clear cell sarcoma
- 17. Congenital mesoblastic nephroma
- 18. Sarcoma (non-clear cell)
- 19. Lymphoma/leukemia
- 20. Other
- F. Histologic grade
- F1. Fuhrman grade (for RCC; grades 1-4): 4
- F2. Ash grade (grade 1-4): #
- F3. WHO grade (grade 1-3): # (for TCCa)
- F4. 1998 WHO/ISUP Classification: #
- 1. LMP 2. LG 3. HG
- F5. Other malignant neoplasms (grades 1-3): #
- G. Non-neoplastic and other conditions: # / # / # / #
- 1. Glomerulopathy
- 2. Interstitial nephritis
- 3. Pyelonephritis
- 4. Nephrolithiasis
- 5. Papillary necrosis
- 6. Chronic parenchymal disease
- 7. Other
- H. Margins of resection: 1 (renal vein) 1. Positive 2. Negative
- I. Mitotic activity: # per 10 high power fields
- J. Angiolymphatic invasion
- J1. Macroscopic (e.g., renal vein thrombus): 1 1. Positive 2. Negative
- J2. Microscopic: 1 1. Positive 2. Negative
- K. Number of positive lymph nodes: N/A
- L. Total number of lymph nodes examined: 0
- M. Extracapsular spread of lymph node metastases: N/A
- 1. Yes 2. No
- N. Adrenal gland:
- N1. Present 1 1. Yes 2. No
- N2. Involvement by renal neoplasm: 2 1. Yes 2. No 3. Not Applicable
- N3. Other adrenal pathology: 2 1. Yes 2. No 3. Not applicable
- O. TNM stage: T 3b N X M X

Source: NCI Genomic Data Commons file 6d90ffc0-a10c-4ba0-9437-0604cd121d23 (TCGA-B0-4827.2A701E0E-3F33-440F-AD5F-BF9A77D53239.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).